Somatic mutation profile of tumor specimen 0DER1Z from CCDI case PBBKLK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.1 years (6,986 days).
Specimen 0DER1Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebf1bf4c-fdf4-4a1e-a47f-32c69616ce19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DER20 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23f45c2e-7e62-4ce2-b5e4-a4ddef6136f1

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, Intron 3, 3'UTR 2, In Frame Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INTS11 | c.146_148del p.S49del | In Frame Del (DEL) | VAF 76/210 reads (36%) | catalogued as rs777963213; called by mutect2, varscan2
- KIT | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553891726, CM119324, COSV55390157, COSV55393817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP74 | c.3426T>A p.H1142Q | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); called by mutect2, varscan2
- FZD8 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- USP28 | c.977T>C p.L326S | Missense Mutation (SNP) | VAF 272/457 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZNF614 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 34/464 reads (7%) | called by muse, mutect2
- DCLRE1C | c.69C>T p.N23= | Silent (SNP) | VAF 47/248 reads (19%) | called by muse, mutect2, varscan2
- EIF1 | c.135T>C p.T45= | Silent (SNP) | VAF 24/750 reads (3%) | catalogued as rs1407402470, COSV60422169; called by muse, mutect2
- FHOD3 | c.2136C>T p.S712= (on ENST00000359247 / NM_001281739.3; = p.S729= on NM_025135.5) | Silent (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- SMC3 | c.2478T>G p.T826= | Silent (SNP) | VAF 43/323 reads (13%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- EIF4A2 | c.999+49G>A | Intron (SNP) | VAF 37/107 reads (35%) | catalogued as rs545310899; called by muse, mutect2, varscan2
- RABGAP1 | c.2424+78T>A | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, varscan2
- SOX11 | c.*1400del | 3'UTR (DEL) | VAF 4/30 reads (13%) | called by mutect2, varscan2
